Somatic mutation profile of tumor specimen HCM-CSHL-0159-C18-01B (aliquot HCM-CSHL-0159-C18-01B-01D-A786-36) from HCMI case HCM-CSHL-0159-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Tumor grade: GB; Age at diagnosis: 61.9 years (22,623 days).
Specimen HCM-CSHL-0159-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e52fc945-6bce-46b1-96ee-e9f8c5f6cf0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0159-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0159-C18-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1de4256-4e73-49fe-8d99-efd9835dd92c

The open-access MAF lists 137 somatic variants for this specimen: 92 protein-altering or splice-affecting, 33 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 33, Intron 8, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, 3'UTR 2, Splice Region 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 38/193 reads (20%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 208/546 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 92/440 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750548939, COSV59371010; called by muse, mutect2, varscan2
- ADAMTSL1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780536559, COSV52810410; called by muse, mutect2, varscan2
- ADCK5 | c.1226A>C p.D409A | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.381); catalogued as rs782208902, COSV58233174; called by muse, mutect2, varscan2
- ADRA1A | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 186/390 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs759868914; called by muse, mutect2, varscan2
- APC | c.3750del p.V1251Ffs*14 | Frame Shift Del (DEL) | VAF 52/177 reads (29%) | catalogued as CM106370; called by mutect2, pindel, varscan2
- AURKA | c.222G>C p.Q74H | Missense Mutation (SNP) | VAF 156/899 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs769911074; called by muse, mutect2, varscan2
- BRD1 | c.3043A>G p.I1015V (on ENST00000216267 / NM_001349940.1; = p.I1146V on NM_001304808.3) | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0.358); catalogued as rs769189277; called by muse, mutect2, varscan2
- BRSK1 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1271951177, COSV58665422; called by muse, mutect2, varscan2
- CAPN6 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 259/375 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759834539, COSV60695723; called by muse, mutect2, varscan2
- CEP290 | c.6417dup p.V2140Sfs*3 | Frame Shift Ins (INS) | VAF 18/169 reads (11%) | catalogued as rs1225676118; called by mutect2, pindel, varscan2
- CFAP299 | c.448dup p.R150Kfs*17 | Frame Shift Ins (INS) | VAF 17/82 reads (21%) | catalogued as rs761800837; called by mutect2, varscan2
- COL1A2 | c.3794C>T p.S1265F | Missense Mutation (SNP) | VAF 109/305 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99798941; called by muse, mutect2, varscan2
- COL4A4 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 119/390 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs55948916; called by muse, mutect2, varscan2
- DHX35 | c.1157C>G p.S386* | Nonsense Mutation (SNP) | VAF 110/670 reads (16%) | catalogued as COSV52669444; called by muse, mutect2, varscan2
- DSCAML1 | c.5961G>C p.E1987D (on ENST00000321322; = p.E1927D on NM_020693.4) | Missense Mutation (SNP) | VAF 122/487 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as COSV58382539; called by muse, mutect2, varscan2
- DSCAML1 | c.4858G>A p.G1620S (on ENST00000321322; = p.G1560S on NM_020693.4) | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as rs756292633; called by muse, mutect2, varscan2
- GALNT17 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1212228242, COSV100352632; called by muse, mutect2, varscan2
- GLI3 | c.4610G>A p.R1537H | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs746798261, COSV67886970; called by muse, mutect2, varscan2
- H3C2 | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1278314228, COSV52517760; called by muse, mutect2
- HOXA6 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56074403; called by muse, mutect2, varscan2
- HYDIN | c.6715C>G p.L2239V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs763638148; called by muse, mutect2, varscan2
- IGFBP6 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201732293; called by muse, mutect2, varscan2
- ITGA9 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1238331400; called by muse, mutect2, varscan2
- IZUMO3 | c.452G>C p.R151P (on ENST00000543880 / NM_001365008.2; = p.R145P on NM_001271706.1) | Missense Mutation (SNP) | VAF 75/386 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs766196413, COSV101371484; called by muse, mutect2, varscan2
- KCNN1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759749668; called by muse, mutect2, varscan2
- LRRC18 | c.402C>A p.D134E | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs748369916; called by muse, mutect2, varscan2
- MAGEE2 | c.1126C>A p.H376N | Missense Mutation (SNP) | VAF 199/310 reads (64%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.816); catalogued as rs1232336885; called by muse, mutect2, varscan2
- MDGA2 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 97/226 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV62108048; called by muse, mutect2, varscan2
- MYF5 | c.271C>G p.R91G | Missense Mutation (SNP) | VAF 122/593 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57356108; called by muse, mutect2, varscan2
- N4BP3 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751253637, COSV51062277; called by muse, mutect2, varscan2
- N4BP3 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs777656725, COSV51066818; called by muse, mutect2, varscan2
- PCDHA7 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.195); catalogued as rs782197887, COSV65337155; called by muse, mutect2, varscan2
- PCDHB15 | c.2220C>A p.S740R | Missense Mutation (SNP) | VAF 86/394 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); catalogued as COSV99179305; called by muse, mutect2, varscan2
- PP2D1 | c.1445G>A p.C482Y | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750617391; called by muse, mutect2, varscan2
- PRB2 | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 39/351 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.048); catalogued as rs1380862911; called by muse, mutect2, varscan2
- PTPRR | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 125/286 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs144918296; called by muse, mutect2, varscan2
- RAPH1 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 77/236 reads (33%) | catalogued as COSV57356059; called by muse, mutect2, varscan2
- RFX4 | c.760G>A p.V254M (on ENST00000392842 / NM_213594.3; = p.V160M on NM_032491.6) | Missense Mutation (SNP) | VAF 104/486 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs759576190, COSV99986103; called by muse, mutect2, varscan2
- TTN | c.21131C>A p.T7044N (on ENST00000591111; = p.T6117N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/364 reads (12%) | PolyPhen benign (0.223); catalogued as rs1425492375; called by mutect2, varscan2
- USP28 | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs550263885, COSV50155875; called by muse, mutect2, varscan2
- UST | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs772986508, COSV66546029; called by muse, mutect2, varscan2
- VAT1L | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as rs748130621; called by muse, mutect2, varscan2
- VPS13B | c.11008G>A p.G3670R | Missense Mutation (SNP) | VAF 300/719 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61754108, COSV62156409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR33 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100459383; called by muse, mutect2, varscan2
- ZFHX4 | c.7015G>T p.E2339* | Nonsense Mutation (SNP) | VAF 113/460 reads (25%) | catalogued as COSV50838972; called by muse, mutect2, varscan2
- ADGRG4 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 128/180 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- AKAP6 | c.4318G>T p.V1440F | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ARHGAP22 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ATG9A | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- BANK1 | c.1903T>C p.F635L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BSN | c.6317A>C p.N2106T | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C7orf57 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 116/397 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CAPZA3 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 65/328 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CNTRL | c.2425G>T p.V809L | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRMP1 | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DNAH10 | c.10024G>T p.E3342* (on ENST00000409039; = p.E3281* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 147/388 reads (38%) | called by muse, mutect2, varscan2
- DNAH9 | c.10606A>C p.I3536L | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- DNER | c.2073C>A p.S691R | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DRAM1 | c.197T>A p.L66H | Missense Mutation (SNP) | VAF 110/277 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DSTYK | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 192/515 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EDRF1 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- EML6 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 123/322 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- EPHA3 | c.1363_1364del p.L455Vfs*6 | Frame Shift Del (DEL) | VAF 53/274 reads (19%) | called by mutect2, pindel, varscan2
- FAM86B2 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- GNS | c.368G>T p.W123L | Missense Mutation (SNP) | VAF 162/723 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRID2IP | c.3577G>T p.D1193Y | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- HTR3D | c.879+8C>G | Splice Region (SNP) | VAF 65/219 reads (30%) | called by muse, mutect2, varscan2
- ITGB1 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1549 | c.2869A>G p.I957V | Missense Mutation (SNP) | VAF 99/418 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MANBA | c.2005C>T p.Q669* (on ENST00000642252; = p.Q623* on NM_005908.4) | Nonsense Mutation (SNP) | VAF 48/254 reads (19%) | called by muse, mutect2, varscan2
- MCC | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NLGN4X | c.1244C>G p.T415S | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- PHLDB1 | c.970A>C p.S324R | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PHLDB1 | c.971G>T p.S324I | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- PNLIP | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 72/300 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POT1 | c.121A>T p.T41S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RAC2 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 40/562 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); called by muse, mutect2
- RAD51AP2 | c.2462T>A p.L821Q | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- RNF139 | c.812A>G p.D271G | Missense Mutation (SNP) | VAF 191/436 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SACS | c.13287_13288del p.Q4430Kfs*34 | Frame Shift Del (DEL) | VAF 18/138 reads (13%) | called by pindel, varscan2
- SLC12A2 | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SLC25A37 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- SUDS3 | c.213-1G>A p.X71_splice | Splice Site (SNP) | VAF 65/328 reads (20%) | called by muse, mutect2, varscan2
- UGT2A3 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- VAPB | c.696T>A p.F232L | Missense Mutation (SNP) | VAF 153/973 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- WAPL | c.2701G>T p.A901S | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- WNK4 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 82/531 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZDHHC15 | c.193T>C p.F65L | Missense Mutation (SNP) | VAF 108/171 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF780B | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ZNF891 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ADARB2 | c.1569C>A p.I523= | Silent (SNP) | VAF 63/195 reads (32%) | catalogued as rs780275876, COSV67232478; called by muse, mutect2, varscan2
- AL031777.2 | c.267C>T p.R89= | Silent (SNP) | VAF 68/327 reads (21%) | catalogued as rs1223145998; called by muse, mutect2, varscan2
- BRSK1 | c.525C>T p.F175= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as rs1222040925, COSV58668022; called by muse, mutect2, varscan2
- CEP89 | c.1137G>A p.E379= | Silent (SNP) | VAF 84/324 reads (26%) | catalogued as COSV59866322; called by muse, mutect2, varscan2
- COL4A2 | c.4047G>A p.R1349= | Silent (SNP) | VAF 27/113 reads (24%) | called by muse, mutect2, varscan2
- CXorf66 | c.183T>C p.F61= | Silent (SNP) | VAF 39/54 reads (72%) | called by muse, varscan2
- DNAI1 | c.537T>A p.T179= | Silent (SNP) | VAF 148/536 reads (28%) | called by muse, mutect2, varscan2
- FAM184B | c.2268C>T p.A756= | Silent (SNP) | VAF 60/260 reads (23%) | catalogued as rs1462473276; called by muse, mutect2, varscan2
- ITIH1 | c.1377C>T p.Y459= | Silent (SNP) | VAF 48/158 reads (30%) | catalogued as rs145303032; called by muse, mutect2, varscan2
- KCNS2 | c.102G>A p.T34= | Silent (SNP) | VAF 145/293 reads (49%) | catalogued as COSV54637628, COSV54639004; called by muse, mutect2, varscan2
- KLHL36 | c.672C>T p.R224= | Silent (SNP) | VAF 124/244 reads (51%) | catalogued as rs745918761; called by muse, mutect2, varscan2
- LVRN | c.291C>T p.R97= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as COSV100773356, COSV100773438; called by mutect2, varscan2
- MED13L | c.171G>T p.L57= | Silent (SNP) | VAF 193/994 reads (19%) | called by muse, mutect2, varscan2
- MYOC | c.1278C>T p.V426= | Silent (SNP) | VAF 359/931 reads (39%) | catalogued as rs1183498744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBEA | c.7407T>A p.P2469= | Silent (SNP) | VAF 44/146 reads (30%) | called by muse, mutect2, varscan2
- NLRP14 | c.2271G>A p.E757= | Silent (SNP) | VAF 15/420 reads (4%) | called by muse, mutect2
- OTUD7A | c.1833C>T p.G611= (on ENST00000307050 / NM_001382637.1; = p.G604= on NM_130901.3) | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as rs760442966; called by muse, mutect2, varscan2
- PANX1 | c.774C>T p.T258= | Silent (SNP) | VAF 105/442 reads (24%) | catalogued as rs775393300; called by muse, mutect2, varscan2
- PBOV1 | c.102G>A p.R34= | Silent (SNP) | VAF 89/411 reads (22%) | called by muse, mutect2, varscan2
- PCDHGB6 | c.1524C>T p.S508= | Silent (SNP) | VAF 74/274 reads (27%) | called by muse, mutect2, varscan2
- PCNX2 | c.4629G>A p.T1543= | Silent (SNP) | VAF 46/247 reads (19%) | catalogued as rs757432332, COSV50780709; called by muse, mutect2, varscan2
- PGAP4 | c.822C>T p.P274= | Silent (SNP) | VAF 94/324 reads (29%) | called by muse, mutect2, varscan2
- POLD2 | c.696G>A p.Q232= | Silent (SNP) | VAF 123/473 reads (26%) | called by muse, mutect2, varscan2
- PRKDC | c.870C>T p.Y290= | Silent (SNP) | VAF 70/388 reads (18%) | catalogued as rs376740223; called by muse, mutect2, varscan2
- PRR23C | c.192C>T p.D64= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs750832767; called by muse, mutect2, varscan2
- PSPH | c.321A>T p.L107= | Silent (SNP) | VAF 141/499 reads (28%) | called by muse, mutect2, varscan2
- TDRD12 | c.651C>T p.N217= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs745807381; called by muse, mutect2, varscan2
- TENM3 | c.1668C>T p.N556= | Silent (SNP) | VAF 87/322 reads (27%) | catalogued as rs372557342, COSV69300737; called by muse, mutect2, varscan2
- THSD1 | c.2154C>A p.T718= | Silent (SNP) | VAF 80/354 reads (23%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.549G>A p.S183= | Silent (SNP) | VAF 105/332 reads (32%) | catalogued as rs762080657; called by muse, varscan2
- ZNF625 | c.538A>C p.R180= | Silent (SNP) | VAF 60/206 reads (29%) | called by muse, mutect2, varscan2
- ZNF835 | c.252C>T p.S84= | Silent (SNP) | VAF 160/633 reads (25%) | catalogued as COSV73379545, COSV73379660; called by muse, mutect2, varscan2
- ZP4 | c.627C>T p.L209= | Silent (SNP) | VAF 69/425 reads (16%) | called by muse, mutect2, varscan2
- ABCA2 | c.*13G>C | 3'UTR (SNP) | VAF 85/377 reads (23%) | called by muse, mutect2, varscan2
- AC245748.1 | c.16-26576C>T | Intron (SNP) | VAF 85/296 reads (29%) | catalogued as rs1212711888, COSV73336506; called by muse, mutect2, varscan2
- CACNA1B | c.530+9150C>T | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, varscan2
- FLI1 | c.-85G>A | 5'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- FOXE1 | c.*7G>A | 3'UTR (SNP) | VAF 135/556 reads (24%) | called by muse, mutect2, varscan2
- HEXD | c.982+237G>A | Intron (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- MACROD2 | c.418+165071G>T | Intron (SNP) | VAF 17/90 reads (19%) | catalogued as rs1339723892; called by muse, mutect2, varscan2
- NDUFV3 | c.170-4782C>T | Intron (SNP) | VAF 79/323 reads (24%) | catalogued as rs767417344; called by muse, mutect2, varscan2
- PIGK | c.987-7016C>G | Intron (SNP) | VAF 123/398 reads (31%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2008C>T | Intron (SNP) | VAF 55/297 reads (19%) | catalogued as rs754443237, COSV57629751; called by muse, mutect2, varscan2
- REXO1L1P | n.1468C>T | RNA (SNP) | VAF 458/3890 reads (12%) | catalogued as rs771837707; called by muse, varscan2
- SETD5 | c.178-174G>T | Intron (SNP) | VAF 80/362 reads (22%) | called by muse, mutect2, varscan2
